Somatic mutation profile of tumor specimen C3N-01823-02 (aliquot CPT0097580009) from CPTAC case C3N-01823, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 63.9 years (23,322 days).
Specimen C3N-01823-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2939c243-6d9f-4f84-a4ea-4781c80ec8ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01823-31 (Blood Derived Normal), aliquot CPT0097610002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d96c6e2c-45c9-4b07-800c-30d3ca3b1fe3

The open-access MAF lists 612 somatic variants for this specimen: 424 protein-altering or splice-affecting, 125 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 366, Silent 125, Intron 33, Nonsense Mutation 25, Frame Shift Del 13, Splice Site 12, RNA 12, 5'Flank 7, 3'Flank 5, 5'UTR 5, Splice Region 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.532del p.H178Tfs*69 | Frame Shift Del (DEL) | VAF 95/473 reads (20%) | catalogued as rs786202525, CD983489, CM111332, COSV52693338, COSV52783253, COSV52816064; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ACSL6 | c.139C>G p.R47G (on ENST00000379240; = p.R72G on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/379 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV57294780; called by muse, mutect2, varscan2
- ALB | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs978356536; called by muse, mutect2
- ARHGAP15 | c.1057G>C p.G353R | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54488261, COSV54490689; called by muse, mutect2
- ARHGAP28 | c.641A>T p.D214V (on ENST00000383472 / NM_001366230.1; = p.D55V on NM_001010000.3) | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV99151338; called by muse, mutect2, varscan2
- ATRNL1 | c.3091T>A p.C1031S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782485662, COSV58073583; called by muse, mutect2, varscan2
- BAZ1B | c.4065C>G p.I1355M | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs140665563; called by muse, mutect2
- BRWD3 | c.1479G>T p.W493C | Missense Mutation (SNP) | VAF 39/201 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100955579; called by muse, mutect2, varscan2
- C6 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 82/446 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.081); catalogued as rs147459672; called by muse, mutect2, varscan2
- CACHD1 | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs949364975; called by muse, mutect2, varscan2
- CACNA1E | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 22/613 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1468245846, COSV62390167; called by muse, mutect2
- CAPN15 | c.2998G>T p.V1000L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV54835701; called by muse, mutect2, varscan2
- CCDC42 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV53448835; called by muse, mutect2, varscan2
- CDC20 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV60522128; called by muse, mutect2, varscan2
- CDC20B | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 110/343 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99696708; called by muse, mutect2, varscan2
- CDKN2A | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58699814, COSV58699889; called by muse, mutect2, varscan2
- CNGB3 | c.485C>A p.P162Q | Missense Mutation (SNP) | VAF 45/460 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60693624; called by muse, mutect2
- COG2 | c.1505C>G p.T502R | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV64188391, COSV64188807; called by muse, mutect2, varscan2
- COL22A1 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 36/351 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57332302, COSV57349347; called by muse, mutect2, varscan2
- COL28A1 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 63/337 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs267601567; called by muse, mutect2, varscan2
- CR2 | c.3062G>A p.R1021Q | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.045); catalogued as rs768446701, COSV65508982; called by muse, mutect2
- CSMD3 | c.8633C>T p.P2878L (on ENST00000297405 / NM_001363185.1; = p.P2709L on NM_052900.3) | Missense Mutation (SNP) | VAF 56/485 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836100; called by muse, mutect2, varscan2
- CSMD3 | c.1612G>A p.D538N (on ENST00000297405 / NM_001363185.1; = p.D434N on NM_052900.3) | Missense Mutation (SNP) | VAF 26/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52252722, COSV99847716; called by muse, mutect2
- CTNND2 | c.3042C>A p.N1014K | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100473497; called by muse, mutect2, varscan2
- DCHS1 | c.8821G>C p.V2941L | Missense Mutation (SNP) | VAF 55/469 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV54998201; called by muse, mutect2, varscan2
- DOCK10 | c.2072A>G p.N691S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.04); catalogued as COSV51367083; called by muse, mutect2
- ELAC2 | c.1766A>T p.Q589L | Missense Mutation (SNP) | VAF 97/550 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.499); catalogued as COSV61644897; called by mutect2, varscan2
- ERVV-1 | c.1123G>C p.D375H | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101654558; called by muse, mutect2, varscan2
- FCRL2 | c.1387G>C p.V463L | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV100829964; called by muse, mutect2
- FHIT | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV59321783; called by muse, mutect2, varscan2
- FLG2 | c.2822G>C p.S941T | Missense Mutation (SNP) | VAF 51/552 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.16); catalogued as COSV66167972; called by muse, mutect2
- GRM8 | c.2526T>G p.I842M | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV58816377; called by muse, mutect2, varscan2
- GSG1L | c.842G>C p.R281T (on ENST00000447459 / NM_001109763.2; = p.R126T on NM_144675.2) | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as COSV66580474; called by muse, mutect2, varscan2
- HCN4 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 54/263 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56086261; called by muse, mutect2, varscan2
- HOXA11 | c.464C>A p.A155D | Missense Mutation (SNP) | VAF 50/646 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758663019; called by muse, mutect2
- IGHV3-16 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.799); catalogued as rs1555446061; called by muse, mutect2
- INHBE | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 31/369 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56989002; called by muse, mutect2
- INTS6L | c.2221G>C p.G741R | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV66084068; called by muse, mutect2, varscan2
- KCNA5 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 118/507 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as BM1480053; called by muse, mutect2, varscan2
- KIAA2013 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs756843643; called by muse, mutect2
- KLHL26 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV56317389; called by muse, mutect2, varscan2
- KLRG1 | c.436G>T p.G146* | Nonsense Mutation (SNP) | VAF 36/266 reads (14%) | catalogued as COSV56942691; called by muse, varscan2
- KMT2D | c.9541G>T p.E3181* | Nonsense Mutation (SNP) | VAF 51/380 reads (13%) | catalogued as COSV99979228; called by muse, mutect2, varscan2
- KPNA5 | c.42G>T p.M14I | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs369865783; called by muse, mutect2, varscan2
- LBH | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs377560679; called by muse, mutect2, varscan2
- LPA | c.3737C>A p.P1246Q | Missense Mutation (SNP) | VAF 46/422 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.227); catalogued as COSV100307231; called by muse, mutect2, varscan2
- LRP1B | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101256729; called by muse, mutect2
- LRPPRC | c.2966G>T p.R989L | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs774857058, COSV53236937; called by muse, mutect2, varscan2
- MAG | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 46/256 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100727951; called by muse, mutect2, varscan2
- MAGEB18 | c.883G>A p.V295I | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.14); catalogued as rs139583296; called by muse, mutect2, varscan2
- MAP7D3 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs756132538; called by muse, mutect2, varscan2
- MYO10 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as rs1306181523; called by muse, mutect2
- NELL1 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV54292798; called by muse, mutect2, varscan2
- NETO2 | c.1531A>T p.R511W | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1298322629; called by muse, mutect2, varscan2
- NOD2 | c.2773G>C p.D925H | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV56054666; called by muse, mutect2
- NOTCH1 | c.949G>A p.G317S | Missense Mutation (SNP) | VAF 44/508 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749696049, COSV99072341; ClinVar: uncertain significance; called by muse, mutect2
- NPAP1 | c.2947A>T p.R983* | Nonsense Mutation (SNP) | VAF 71/296 reads (24%) | catalogued as COSV100275547; called by muse, mutect2, varscan2
- NPBWR2 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764589585; called by muse, mutect2, varscan2
- NPHS1 | c.840+1G>T p.X280_splice | Splice Site (SNP) | VAF 38/466 reads (8%) | catalogued as rs1374214589, CS127671; called by muse, mutect2
- NPHS1 | c.358C>A p.P120T | Missense Mutation (SNP) | VAF 59/575 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); catalogued as rs759093283; called by muse, mutect2, varscan2
- NRXN1 | c.2386G>T p.E796* | Nonsense Mutation (SNP) | VAF 16/202 reads (8%) | catalogued as COSV58459244, COSV58493099; called by muse, mutect2
- NSMF | c.850G>T p.E284* (on ENST00000371475 / NM_001130969.3; = p.E282* on NM_015537.4) | Nonsense Mutation (SNP) | VAF 18/170 reads (11%) | catalogued as rs1477685228; called by muse, mutect2
- OR5AC2 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs755877682, COSV62279133; called by muse, mutect2, varscan2
- OR5L1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs745385243, COSV61733573, COSV61734273, COSV61735834; called by muse, varscan2
- OR5M1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV101591540; called by muse, mutect2
- OR5T1 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.521); catalogued as rs779133740; called by muse, mutect2
- OR5T2 | c.410T>C p.V137A | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57588127; called by muse, mutect2, varscan2
- OR8B4 | c.745C>G p.L249V | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV62069773; called by muse, mutect2
- OR8B4 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62069509; called by muse, mutect2
- OR8H1 | c.423C>A p.C141* | Nonsense Mutation (SNP) | VAF 40/226 reads (18%) | catalogued as rs772055350, COSV57296218; called by muse, mutect2, varscan2
- OVCH1 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 20/572 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV58959847; called by muse, mutect2
- PANX1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs189649511; called by muse, mutect2, varscan2
- PBX3 | c.1007C>G p.S336C | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60734553; called by muse, mutect2, varscan2
- PCDH11X | c.3652G>T p.A1218S | Missense Mutation (SNP) | VAF 107/437 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.018); catalogued as rs1462233761, COSV53516663; called by muse, mutect2, varscan2
- PCDHB6 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 38/447 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.261); catalogued as rs1554277616, COSV50700351; called by muse, mutect2
- PCDHB7 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50755681; called by muse, mutect2, varscan2
- PCDHGB4 | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230521211; called by muse, mutect2, varscan2
- PDZRN4 | c.2879G>T p.R960L (on ENST00000402685 / NM_001164595.2; = p.R702L on NM_013377.4) | Missense Mutation (SNP) | VAF 204/413 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54216779; called by muse, mutect2, varscan2
- PHACTR3 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV63033377; called by muse, mutect2, varscan2
- PHKA2 | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 30/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66056776; called by muse, mutect2, varscan2
- PKD1L1 | c.6140G>T p.W2047L | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs759292307; called by muse, mutect2, varscan2
- POM121L12 | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 39/275 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as COSV68693395; called by muse, mutect2, varscan2
- PPRC1 | c.3671A>G p.N1224S | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs761032678; called by muse, mutect2, varscan2
- PTGIS | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 95/372 reads (26%) | catalogued as COSV54837117, COSV54840735; called by muse, mutect2, varscan2
- PTPRT | c.1526C>A p.P509H | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62015376; called by mutect2, varscan2
- RAPGEF2 | c.3037G>C p.D1013H | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV52431030; called by muse, mutect2, varscan2
- RBM6 | c.3334del p.R1112Efs*? | Frame Shift Del (DEL) | VAF 24/235 reads (10%) | catalogued as COSV56481082; called by mutect2, pindel
- RHPN1 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs371512488; called by muse, mutect2
- RYR1 | c.6184C>A p.R2062S | Missense Mutation (SNP) | VAF 52/583 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV62092924; called by muse, mutect2
- SCN10A | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV71860290; called by muse, mutect2
- SERPINA6 | c.714C>A p.S238R | Missense Mutation (SNP) | VAF 26/492 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58583986; called by muse, mutect2
- SERPINB1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 57/373 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as rs761685123, COSV66313866; called by muse, mutect2, varscan2
- SHANK1 | c.3663C>A p.S1221R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99521253; called by muse, varscan2
- SLC45A1 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs1156933937; called by muse, mutect2
- SLC6A5 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); catalogued as CD127474, COSV54226208; called by muse, mutect2, varscan2
- SLIT3 | c.1786G>T p.V596L | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs562240210, COSV60606132; called by muse, mutect2, varscan2
- SMARCA4 | c.3774+1G>T p.X1258_splice | Splice Site (SNP) | VAF 105/487 reads (22%) | catalogued as COSV60789753; called by muse, mutect2, varscan2
- SMARCA5 | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.45); catalogued as COSV51642367; called by muse, mutect2, varscan2
- SNIP1 | c.212G>C p.R71P | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); catalogued as rs866431182; called by muse, mutect2
- SNRNP200 | c.3426G>C p.K1142N | Missense Mutation (SNP) | VAF 25/622 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV60489324; called by muse, mutect2
- SPRR2F | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 79/483 reads (16%) | catalogued as rs1361166494; called by muse, mutect2, varscan2
- SSUH2 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 23/157 reads (15%) | catalogued as rs779838788; called by muse, mutect2, varscan2
- STK11 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100480677; called by mutect2, varscan2
- STK11 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 62/391 reads (16%) | catalogued as COSV58825370; called by muse, mutect2, varscan2
- SVIL | c.6160G>A p.E2054K (on ENST00000355867 / NM_021738.3; = p.E1628K on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/217 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs1400236411; called by muse, mutect2
- TECTA | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs149935047; called by muse, mutect2, varscan2
- TMEM132A | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 28/263 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV50002958, COSV99137185; called by muse, mutect2, varscan2
- TMEM30A | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100034644; called by muse, mutect2, varscan2
- TNRC6C | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1212900362, COSV56940092; called by muse, mutect2, varscan2
- TNS3 | c.1369G>T p.V457L | Missense Mutation (SNP) | VAF 124/561 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.067); catalogued as rs751534391, COSV100235165, COSV60788015; called by muse, mutect2, varscan2
- TPR | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV66606125; called by muse, mutect2
- TRIM28 | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1481907545; called by muse, mutect2, varscan2
- TRIM58 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV63572333; called by muse, varscan2
- TRPM6 | c.4656G>T p.K1552N | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV62517110; called by muse, mutect2
- UBR1 | c.3866G>T p.S1289I | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); catalogued as COSV51933890; called by muse, mutect2, varscan2
- UNC45B | c.1691C>A p.A564E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as rs1434641920; called by muse, varscan2
- UNC80 | c.4410G>C p.Q1470H | Missense Mutation (SNP) | VAF 60/336 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.991); catalogued as COSV99779004; called by muse, mutect2, varscan2
- USH2A | c.8776G>C p.E2926Q | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV56393642; called by muse, mutect2
- USP15 | c.2089G>C p.E697Q (on ENST00000280377 / NM_001351159.2; = p.E668Q on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV54794227; called by muse, mutect2
- WDFY4 | c.2708C>A p.S903* | Nonsense Mutation (SNP) | VAF 32/256 reads (13%) | catalogued as COSV57451071; called by muse, mutect2, varscan2
- XIRP2 | c.508C>A p.Q170K (on ENST00000628543; = p.Q345K on NM_152381.6) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs1329024194, COSV54697810, COSV99743438; called by muse, mutect2
- ZNF223 | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as rs1179556188; called by muse, varscan2
- ZNF257 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1400263933, COSV71311074; called by muse, mutect2, varscan2
- ZNF366 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV59218184; called by muse, mutect2, varscan2
- ZNF423 | c.1113C>A p.S371R (on ENST00000563137 / NM_001379286.1; = p.S363R on NM_015069.4) | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV99284415; called by muse, mutect2
- ZNF518A | c.4186C>T p.P1396S | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781991518; called by muse, mutect2
- ZNF99 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs957814127; called by muse, mutect2, varscan2
- ABCA13 | c.11920C>G p.R3974G | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AC126283.2 | c.1036G>T p.A346S | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS16 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2
- ADARB2 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 32/277 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ADCK1 | c.1511G>C p.G504A | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, varscan2
- ADGRA1 | c.529A>G p.N177D | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); called by muse, mutect2
- ADRA2C | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.191); called by muse, mutect2
- AGMO | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- AKAP4 | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AMPH | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ARHGAP24 | c.455C>A p.A152D (on ENST00000395184 / NM_001025616.3; = p.A59D on NM_031305.3) | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- ARMC4 | c.1427T>A p.M476K | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ASB2 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.109); called by muse, mutect2
- ATAD2B | c.41C>G p.S14C | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2
- BRCA2 | c.1159G>C p.V387L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.269); called by muse, mutect2
- C20orf141 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- C20orf203 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- C2CD5 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 28/676 reads (4%) | called by muse, mutect2
- C2orf81 | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C6orf141 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2
- CALR3 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- CAPS2 | c.648A>T p.A216= | Splice Region (SNP) | VAF 32/155 reads (21%) | called by muse, mutect2, varscan2
- CASK | c.1006A>T p.T336S | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.031); called by muse, mutect2
- CCDC166 | c.985C>A p.R329S | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2
- CCDC168 | c.18632C>A p.A6211E | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.643); called by muse, mutect2
- CCDC178 | c.1774G>T p.D592Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- CCL11 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 16/434 reads (4%) | called by muse, mutect2
- CCNT1 | c.1784C>G p.T595S | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CDC14C | c.1538G>T p.R513M (on ENST00000428251; = p.R406M on NM_152627.3) | Missense Mutation (SNP) | VAF 116/1109 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CDC73 | c.1369T>G p.W457G | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CDH23 | c.7001C>A p.T2334N | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.387); called by muse, varscan2
- CHD7 | c.3076T>C p.S1026P | Missense Mutation (SNP) | VAF 29/340 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHRNA1 | c.613C>T p.P205S (on ENST00000261007 / NM_001039523.3; = p.P180S on NM_000079.4) | Missense Mutation (SNP) | VAF 58/384 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- CHST2 | c.721G>T p.G241W | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CLSTN3 | c.65-3del | Splice Region (DEL) | VAF 110/516 reads (21%) | called by mutect2, pindel, varscan2
- CLTCL1 | c.3116G>C p.R1039P | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CNTN5 | c.488G>T p.S163I | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- COL27A1 | c.4825del p.R1609Efs*141 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- COL9A1 | c.1894C>A p.P632T | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- CPED1 | c.2598del p.N867Ifs*10 | Frame Shift Del (DEL) | VAF 45/284 reads (16%) | called by mutect2, pindel, varscan2
- CPZ | c.1481C>G p.S494* (on ENST00000360986 / NM_001014447.3; = p.S483* on NM_003652.3) | Nonsense Mutation (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- CRX | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CSMD1 | c.9086C>G p.T3029S (on ENST00000520002; = p.T3028S on NM_033225.6) | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.026); called by muse, mutect2
- CSMD1 | c.7998T>A p.N2666K (on ENST00000520002; = p.N2665K on NM_033225.6) | Missense Mutation (SNP) | VAF 12/165 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CSMD1 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.2823G>T p.Q941H (on ENST00000297405 / NM_001363185.1; = p.Q837H on NM_052900.3) | Missense Mutation (SNP) | VAF 25/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CST2 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CUL9 | c.940G>T p.V314L | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP19A1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP4F11 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 15/196 reads (8%) | called by muse, mutect2
- DACT3 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.03); called by muse, mutect2
- DCHS2 | c.1025G>A p.G342E | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); called by muse, mutect2
- DCLRE1C | c.1303T>A p.C435S (on ENST00000378278 / NM_001350965.2; = p.C320S on NM_022487.4) | Missense Mutation (SNP) | VAF 51/245 reads (21%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND5B | c.1577A>C p.Q526P | Missense Mutation (SNP) | VAF 46/386 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX30 | c.404A>T p.D135V (on ENST00000445061 / NM_138615.3; = p.D96V on NM_014966.3) | Missense Mutation (SNP) | VAF 39/432 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2
- DNAH17 | c.4139C>A p.T1380K | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DOC2B | c.453+1G>T p.X151_splice | Splice Site (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- DOCK10 | c.1330G>T p.V444L | Missense Mutation (SNP) | VAF 60/393 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, varscan2
- DOCK2 | c.782G>T p.W261L | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DOCK2 | c.4545G>T p.Q1515H | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- DSC2 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 70/484 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- DST | c.18023G>T p.G6008V (on ENST00000361203 / NM_001374722.1; = p.G3705V on NM_015548.5) | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- DUSP12 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.467); called by muse, mutect2
- DUSP15 | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFTUD2 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 76/274 reads (28%) | called by muse, mutect2, varscan2
- EGR4 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- EPC2 | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ESPN | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 42/340 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); called by muse, varscan2
- EXOSC7 | c.295G>C p.D99H | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- F13B | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- F7 | c.246C>A p.C82* | Nonsense Mutation (SNP) | VAF 32/310 reads (10%) | called by muse, mutect2, varscan2
- FAM135B | c.2303C>A p.T768N | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM47B | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- FAT1 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT4 | c.10543A>T p.S3515C | Missense Mutation (SNP) | VAF 36/400 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2
- FIGNL2 | c.1595T>A p.V532E | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FMN2 | c.2540C>T p.S847F | Missense Mutation (SNP) | VAF 134/531 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FRMD4B | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- GABRP | c.170G>A p.G57D | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- GALNTL6 | c.248-2A>T p.X83_splice | Splice Site (SNP) | VAF 24/82 reads (29%) | called by muse, varscan2
- GAPVD1 | c.3595C>G p.L1199V (on ENST00000394104; = p.L1208V on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GCDH | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.933); called by muse, mutect2
- GFRA2 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); called by muse, mutect2
- GPATCH1 | c.2637G>T p.K879N | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPM6A | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- GPR32 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK1 | c.2348C>A p.T783K | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIK3 | c.1466del p.G489Afs*31 | Frame Shift Del (DEL) | VAF 46/492 reads (9%) | called by mutect2, pindel
- GRM5 | c.910A>T p.S304C | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H3C7 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 152/658 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HECW1 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2
- HECW2 | c.3223G>C p.D1075H | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- HIPK3 | c.2945C>G p.S982C | Missense Mutation (SNP) | VAF 39/473 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- HPS3 | c.1600A>T p.M534L | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, varscan2
- ICE1 | c.3412G>T p.A1138S | Missense Mutation (SNP) | VAF 30/331 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); called by muse, mutect2
- ICE1 | c.5353A>T p.N1785Y | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.438); called by muse, mutect2
- IFNL1 | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGFN1 | c.3271G>T p.A1091S (on ENST00000295591 / NM_001367841.1; = p.A3548S on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- IGHD | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.355); called by muse, mutect2
- IGKV1-8 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 111/565 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IGSF9 | c.1036G>T p.V346F (on ENST00000368094 / NM_001135050.2; = p.V330F on NM_020789.4) | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- IL4R | c.2018G>T p.S673I | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- INTS1 | c.2373G>A p.M791I | Missense Mutation (SNP) | VAF 97/501 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- IPCEF1 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- ITIH5 | c.907A>C p.S303R | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- IZUMO1R | c.524C>A p.P175Q (on ENST00000440961; = p.P182Q on NM_001199206.3) | Missense Mutation (SNP) | VAF 66/395 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- IZUMO1R | c.649C>A p.R217S (on ENST00000440961; = p.R224S on NM_001199206.3) | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, varscan2
- JARID2 | c.1636G>T p.G546C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- KCNA10 | c.174C>A p.N58K | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH2 | c.2089C>A p.L697I | Missense Mutation (SNP) | VAF 40/347 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KCNQ3 | c.2232G>T p.R744S | Missense Mutation (SNP) | VAF 44/388 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNU1 | c.1794-1G>T p.X598_splice | Splice Site (SNP) | VAF 26/151 reads (17%) | called by muse, mutect2, varscan2
- KEAP1 | c.1500C>G p.I500M | Missense Mutation (SNP) | VAF 20/350 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.049); called by muse, mutect2
- KIAA2013 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 25/376 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); called by muse, mutect2
- KIF3C | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 49/368 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KLHL1 | c.2188-2A>C p.X730_splice | Splice Site (SNP) | VAF 28/157 reads (18%) | called by muse, mutect2, varscan2
- KLRC3 | c.87C>A p.S29R | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT24 | c.75C>A p.S25R | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- KRTDAP | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- KSR2 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 78/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAIR1 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 34/360 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.888); called by muse, mutect2
- LAMA1 | c.7896G>T p.E2632D | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- LAMA5 | c.6933G>T p.Q2311H | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LILRA1 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- LPCAT4 | c.712-1G>T p.X238_splice | Splice Site (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- LRP1B | c.13082G>A p.C4361Y | Missense Mutation (SNP) | VAF 19/497 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LRP2 | c.5804G>T p.W1935L | Missense Mutation (SNP) | VAF 70/542 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC7 | c.640C>A p.L214I (on ENST00000651989 / NM_001370785.2; = p.L181I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2
- LRRC7 | c.641T>C p.L214P (on ENST00000651989 / NM_001370785.2; = p.L181P on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MALT1 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.048); called by muse, mutect2
- MAN2C1 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF10 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 115/653 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCO | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MATR3 | c.1029C>A p.F343L | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.045); called by muse, mutect2
- MBD1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 102/642 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, varscan2
- MBIP | c.76T>A p.S26T | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); called by muse, mutect2
- MCM9 | c.2245G>A p.A749T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- MDH1B | c.658A>G p.K220E | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2
- MED1 | c.4144A>G p.K1382E | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- MED17 | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 104/680 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.045); called by muse, varscan2
- MFNG | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.045); called by muse, mutect2
- MFSD14B | c.421T>C p.S141P | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MGST3 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 45/588 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.04); called by muse, mutect2
- MICALL2 | c.2034C>A p.N678K | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- MINDY4B | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLLT1 | c.266T>G p.F89C | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOCOS | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 28/530 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); called by muse, mutect2
- MOCS3 | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- MORC2 | c.380G>T p.C127F (on ENST00000397641 / NM_001303256.3; = p.C65F on NM_014941.3) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MROH2B | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 32/338 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2
- MRPL46 | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 88/495 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A12 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MTF1 | c.2237G>T p.G746V | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- MUC1 | c.3469G>A p.A1157T (on ENST00000611571 / NM_001371720.1; = p.A168T on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2
- MUC16 | c.10954G>T p.V3652L | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYH7 | c.3005C>A p.A1002D | Missense Mutation (SNP) | VAF 103/554 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- MYO1E | c.991A>T p.K331* | Nonsense Mutation (SNP) | VAF 87/471 reads (18%) | called by muse, mutect2, varscan2
- MYO7B | c.1597G>T p.A533S | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MYOCD | c.1894del p.Q632Sfs*12 | Frame Shift Del (DEL) | VAF 53/278 reads (19%) | called by mutect2, pindel, varscan2
- MYOM3 | c.403-2A>C p.X135_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- MYRIP | c.913C>A p.L305M | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NANOS2 | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NELL2 | c.2437C>G p.L813V | Missense Mutation (SNP) | VAF 49/374 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NID2 | c.2675-3C>A | Splice Region (SNP) | VAF 49/515 reads (10%) | called by muse, mutect2
- NLGN4X | c.1274C>A p.T425K | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOX3 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- NOX4 | c.1135+1G>T p.X379_splice | Splice Site (SNP) | VAF 17/107 reads (16%) | called by muse, mutect2, varscan2
- NSMF | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- NUCB2 | c.1256-1G>T p.X419_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | called by mutect2, varscan2
- NUDT19 | c.1039C>G p.R347G | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NUS1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OPRK1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 38/338 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OR10X1 | c.108C>A p.Y36* | Nonsense Mutation (SNP) | VAF 38/400 reads (10%) | called by muse, mutect2
- OR11L1 | c.753C>G p.Y251* | Nonsense Mutation (SNP) | VAF 48/453 reads (11%) | called by muse, mutect2, varscan2
- OR14I1 | c.520C>A p.Q174K | Missense Mutation (SNP) | VAF 83/426 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2C1 | c.550A>G p.M184V | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- OR2T1 | c.394C>A p.P132T | Missense Mutation (SNP) | VAF 26/282 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- OR51B4 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 68/366 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR56A3 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OR5D16 | c.119G>T p.S40I | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- OR5H14 | c.799G>T p.A267S | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OR5V1 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.152); called by mutect2, varscan2
- OR8K3 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OTOF | c.352T>C p.Y118H | Missense Mutation (SNP) | VAF 48/523 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- OTOGL | c.1264G>A p.D422N (on ENST00000547103; = p.D413N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- P2RY10 | c.648G>T p.W216C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.568G>A p.E190K (on ENST00000374531 / NM_001037293.2; = p.E222K on NM_053016.6) | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PAX5 | c.1085dup p.N362Kfs*12 | Frame Shift Ins (INS) | VAF 16/142 reads (11%) | called by mutect2, pindel, varscan2
- PCDH10 | c.2496del p.D833Tfs*2 | Frame Shift Del (DEL) | VAF 39/242 reads (16%) | called by mutect2, pindel, varscan2
- PCDH17 | c.1826C>A p.T609N | Missense Mutation (SNP) | VAF 37/339 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDH7 | c.2874G>T p.K958N | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); called by muse, mutect2
- PCDHB8 | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 114/642 reads (18%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PGR | c.1907-4G>T | Splice Region (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- PGR | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 81/616 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3C2G | c.910A>G p.M304V | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PKD1L1 | c.5812G>C p.V1938L | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLCB3 | c.519G>A p.K173= | Splice Region (SNP) | VAF 17/510 reads (3%) | called by muse, mutect2
- PLEKHH1 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.269); called by muse, mutect2
- PLRG1 | c.557del p.P186Qfs*43 | Frame Shift Del (DEL) | VAF 28/331 reads (8%) | called by mutect2, pindel
- PRKD3 | c.501C>G p.F167L | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- PRR19 | c.645G>C p.W215C | Missense Mutation (SNP) | VAF 44/496 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2
- PRSS55 | c.954A>T p.K318N | Missense Mutation (SNP) | VAF 21/173 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PSME3IP1 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- PTCHD4 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 49/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTPMT1 | c.500C>A p.S167* | Nonsense Mutation (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- PWP1 | c.370A>T p.N124Y | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- RAB3IP | c.222A>T p.L74F (on ENST00000550536 / NM_175623.4; = p.L58F on NM_022456.5) | Missense Mutation (SNP) | VAF 129/455 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAG1 | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 69/474 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBPJL | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RELN | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 123/462 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RFESD | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2
- RFWD3 | c.1217A>C p.H406P | Missense Mutation (SNP) | VAF 59/315 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RNASE8 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 17/324 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2
- RPUSD3 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RREB1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RSPH9 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- RYR2 | c.3412del p.D1138Mfs*31 | Frame Shift Del (DEL) | VAF 59/235 reads (25%) | called by mutect2, pindel, varscan2
- SARDH | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD2 | c.6750A>T p.Q2250H | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETX | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 86/525 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SFI1 | c.2371del p.L791Wfs*110 (on ENST00000400288 / NM_001007467.3; = p.L760Wfs*110 on NM_014775.4) | Frame Shift Del (DEL) | VAF 13/157 reads (8%) | called by mutect2, pindel
- SH2B1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 16/310 reads (5%) | called by muse, mutect2
- SHISA9 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHROOM2 | c.798T>A p.S266R | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM4 | c.3671G>C p.G1224A | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SIGLEC5 | c.1035G>C p.E345D | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SLC19A1 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.929); called by muse, mutect2
- SLC22A24 | c.666A>C p.L222F | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); called by muse, mutect2
- SLC25A20 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC35C1 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 52/551 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2
- SLC4A7 | c.2986C>G p.P996A | Missense Mutation (SNP) | VAF 14/420 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9B2 | c.890G>A p.G297D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.418); called by muse, mutect2
- SMG6 | c.2213A>C p.Y738S | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNAPC4 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 66/391 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNTG1 | c.1163C>G p.A388G | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SNX20 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- SP9 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SPAST | c.1333A>T p.S445C | Missense Mutation (SNP) | VAF 62/334 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPINK4 | c.94C>A p.R32S | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- SPIRE2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 45/250 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOCK3 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SRBD1 | c.2533_2536del p.G845Hfs*14 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- STKLD1 | c.246C>G p.H82Q | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R3 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.014); called by muse, varscan2
- TCAP | c.181G>T p.V61L | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- TENM2 | c.1474G>T p.G492C (on ENST00000518659 / NM_001122679.2; = p.G260C on NM_001080428.3) | Missense Mutation (SNP) | VAF 60/390 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- TEP1 | c.1154A>C p.H385P | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TET3 | c.995C>G p.S332C | Missense Mutation (SNP) | VAF 24/523 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by muse, mutect2
- TEX13C | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TG | c.5105C>G p.S1702C | Missense Mutation (SNP) | VAF 56/554 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TGFBR3L | c.277-16_305del p.X93_splice | Splice Site (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel
- TGM6 | c.113T>C p.F38S | Missense Mutation (SNP) | VAF 155/721 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THAP1 | c.170A>T p.H57L | Missense Mutation (SNP) | VAF 47/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TK1 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.035); called by muse, mutect2
- TK2 | c.550C>T p.H184Y (on ENST00000299697; = p.H240Y on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/611 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TLN2 | c.3737A>G p.Q1246R | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- TNKS1BP1 | c.3721G>T p.V1241F | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TRAPPC9 | c.2475del p.Q826Rfs*12 | Frame Shift Del (DEL) | VAF 60/646 reads (9%) | called by mutect2, pindel
- TRAV6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 49/253 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, varscan2
- TREML2 | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 46/333 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TSEN15 | c.293A>C p.E98A | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.588); called by muse, mutect2
- TTF1 | c.1178A>C p.K393T | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- U2SURP | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- UBA7 | c.1384G>T p.G462W | Missense Mutation (SNP) | VAF 47/316 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2D1 | c.61T>A p.C21S | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UBFD1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UEVLD | c.1166C>G p.S389C | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- UNC5D | c.1084+1G>T p.X362_splice | Splice Site (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- USP6 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 65/375 reads (17%) | called by muse, mutect2, varscan2
- USP9X | c.1199del p.L400Cfs*11 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- VCAN | c.6742G>C p.D2248H | Missense Mutation (SNP) | VAF 83/478 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- VIM | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 66/544 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.346); called by muse, varscan2
- WASF1 | c.1560G>T p.Q520H | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WDR72 | c.3011dup p.L1004Ffs*8 | Frame Shift Ins (INS) | VAF 36/215 reads (17%) | called by mutect2, pindel, varscan2
- WDR87 | c.7522C>A p.L2508I | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- WNK1 | c.5842G>T p.V1948L (on ENST00000315939 / NM_018979.4; = p.V1700L on NM_014823.3) | Missense Mutation (SNP) | VAF 119/765 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XAB2 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.344); called by muse, mutect2
- XIRP1 | c.4538C>A p.A1513D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- XPC | c.25G>A p.G9R | Missense Mutation (SNP) | VAF 13/349 reads (4%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2
- XRCC4 | c.653G>C p.C218S | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB6 | c.134A>C p.Q45P | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ZDBF2 | c.555T>A p.N185K | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZFYVE16 | c.756T>G p.S252R | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.274); called by muse, mutect2
- ZHX2 | c.1376T>A p.L459H | Missense Mutation (SNP) | VAF 64/472 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZHX2 | c.1478G>T p.R493L | Missense Mutation (SNP) | VAF 52/366 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZIC1 | c.312C>G p.N104K | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.925); called by muse, mutect2
- ZNF226 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF335 | c.3271C>A p.R1091S | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- ZNF383 | c.857T>A p.V286E | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ZNF407 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.174); called by muse, mutect2
- ZNF416 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 39/262 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF556 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF578 | c.1007G>T p.C336F | Missense Mutation (SNP) | VAF 44/422 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- ZNF628 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- ZNF808 | c.1982G>T p.S661I | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- ZNF98 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by mutect2, varscan2
- ADAMTS12 | c.4086C>A p.L1362= | Silent (SNP) | VAF 44/223 reads (20%) | catalogued as COSV61265791; called by muse, mutect2, varscan2
- ADAMTS7 | c.4251G>C p.A1417= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as COSV66306360; called by muse, mutect2, varscan2
- ADGRG7 | c.2217G>A p.S739= | Silent (SNP) | VAF 18/411 reads (4%) | catalogued as rs1385549698, COSV56296000; called by muse, mutect2
- AGBL2 | c.1476T>A p.I492= | Silent (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- AHNAK | c.7728C>A p.A2576= | Silent (SNP) | VAF 74/429 reads (17%) | called by muse, mutect2, varscan2
- AL121899.2 | c.1965C>A p.G655= | Silent (SNP) | VAF 87/375 reads (23%) | catalogued as rs780647083; called by muse, mutect2, varscan2
- ALK | c.3147C>A p.V1049= | Silent (SNP) | VAF 70/393 reads (18%) | called by muse, mutect2, varscan2
- ALPP | c.543C>G p.T181= | Silent (SNP) | VAF 41/390 reads (11%) | called by muse, mutect2, varscan2
- ANKRD16 | c.483A>G p.P161= | Silent (SNP) | VAF 63/371 reads (17%) | called by muse, mutect2, varscan2
- ASCC3 | c.36C>A p.S12= | Silent (SNP) | VAF 22/360 reads (6%) | catalogued as COSV100225170; called by muse, mutect2
- ATP10A | c.4089C>T p.S1363= | Silent (SNP) | VAF 48/180 reads (27%) | catalogued as COSV63526467; called by muse, mutect2, varscan2
- AXDND1 | c.316C>A p.R106= | Silent (SNP) | VAF 47/228 reads (21%) | catalogued as rs577148644, COSV62642783, COSV62647866; called by muse, mutect2, varscan2
- BMP5 | c.312C>A p.S104= | Silent (SNP) | VAF 87/427 reads (20%) | called by muse, mutect2, varscan2
- CACNA1B | c.5979G>C p.L1993= | Silent (SNP) | VAF 36/204 reads (18%) | called by muse, mutect2, varscan2
- CASK | c.1008C>T p.T336= | Silent (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2
- CDC42BPG | c.3105G>A p.L1035= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- CEACAM5 | c.441C>T p.P147= | Silent (SNP) | VAF 107/389 reads (28%) | catalogued as rs782301321; called by muse, mutect2, varscan2
- CHRNB3 | c.726C>A p.I242= | Silent (SNP) | VAF 42/254 reads (17%) | catalogued as COSV51495900; called by muse, mutect2, varscan2
- CLDN8 | c.210G>T p.L70= | Silent (SNP) | VAF 41/186 reads (22%) | called by muse, mutect2, varscan2
- CLTCL1 | c.4131C>T p.T1377= | Silent (SNP) | VAF 15/267 reads (6%) | called by muse, mutect2
- COL22A1 | c.3030C>A p.V1010= | Silent (SNP) | VAF 38/326 reads (12%) | called by muse, varscan2
- CPN2 | c.351C>T p.F117= | Silent (SNP) | VAF 72/297 reads (24%) | catalogued as rs1442822708; called by muse, mutect2, varscan2
- CPNE2 | c.888C>T p.F296= | Silent (SNP) | VAF 44/267 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.2010C>A p.P670= (on ENST00000297405 / NM_001363185.1; = p.P566= on NM_052900.3) | Silent (SNP) | VAF 22/276 reads (8%) | catalogued as COSV52120981; called by muse, mutect2
- CYB561 | c.744C>A p.P248= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- CYP4F11 | c.609G>C p.L203= | Silent (SNP) | VAF 61/299 reads (20%) | called by muse, mutect2, varscan2
- DHX37 | c.2487G>T p.L829= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as COSV58139168; called by muse, mutect2, varscan2
- DSTYK | c.15G>T p.G5= | Silent (SNP) | VAF 29/94 reads (31%) | called by muse, varscan2
- DYNC1I1 | c.993C>A p.T331= | Silent (SNP) | VAF 56/252 reads (22%) | called by muse, mutect2, varscan2
- DYRK1A | c.1848C>T p.H616= | Silent (SNP) | VAF 58/306 reads (19%) | called by muse, mutect2, varscan2
- F13A1 | c.1152T>A p.P384= | Silent (SNP) | VAF 118/689 reads (17%) | called by muse, mutect2, varscan2
- F9 | c.549T>A p.V183= | Silent (SNP) | VAF 30/175 reads (17%) | called by muse, mutect2, varscan2
- GPR139 | c.630C>G p.L210= | Silent (SNP) | VAF 34/253 reads (13%) | called by muse, mutect2, varscan2
- HACL1 | c.1314G>T p.V438= | Silent (SNP) | VAF 64/342 reads (19%) | called by muse, varscan2
- HAUS4 | c.159G>A p.E53= | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as rs1453932363; called by muse, mutect2
- HIPK2 | c.2325G>A p.V775= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- HLA-DQA2 | c.30G>T p.G10= | Silent (SNP) | VAF 103/377 reads (27%) | called by muse, mutect2, varscan2
- HM13 | c.162C>T p.S54= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as rs1271259078; called by muse, mutect2
- IFT122 | c.3300A>G p.E1100= (on ENST00000348417 / NM_052989.3; = p.E1041= on NM_018262.4) | Silent (SNP) | VAF 62/818 reads (8%) | catalogued as rs1388477029; called by muse, mutect2
- INSYN1 | c.186G>T p.S62= | Silent (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- ITSN1 | c.1047G>T p.T349= | Silent (SNP) | VAF 31/174 reads (18%) | catalogued as rs777953537, COSV66082655; called by muse, varscan2
- KCNB2 | c.2013A>T p.P671= | Silent (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- KIF1A | c.4419A>G p.R1473= (on ENST00000320389 / NM_001379639.1; = p.R1465= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 41/291 reads (14%) | called by muse, mutect2, varscan2
- KIF3C | c.1024C>T p.L342= | Silent (SNP) | VAF 24/270 reads (9%) | catalogued as rs889654231; called by muse, mutect2
- KLRG2 | c.1170G>C p.T390= | Silent (SNP) | VAF 54/504 reads (11%) | called by muse, mutect2, varscan2
- KRT72 | c.936C>A p.A312= | Silent (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- KY | c.1851G>A p.L617= | Silent (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- LILRB5 | c.1527C>A p.G509= (on ENST00000449561 / NM_001081442.3; = p.G508= on NM_006840.5) | Silent (SNP) | VAF 15/180 reads (8%) | called by muse, mutect2
- LPA | c.3738A>G p.P1246= | Silent (SNP) | VAF 45/419 reads (11%) | called by muse, mutect2, varscan2
- MAST3 | c.3561C>T p.S1187= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as rs1376931207; called by muse, mutect2, varscan2
- MMP9 | c.292C>A p.R98= | Silent (SNP) | VAF 81/481 reads (17%) | called by muse, mutect2, varscan2
- MRPL21 | c.606G>T p.P202= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as COSV62913111; called by muse, mutect2, varscan2
- MTTP | c.369G>T p.T123= | Silent (SNP) | VAF 22/300 reads (7%) | catalogued as COSV99645309; called by muse, mutect2
- MTTP | c.1404G>A p.E468= | Silent (SNP) | VAF 50/586 reads (9%) | called by muse, mutect2
- MYO3A | c.2826G>C p.V942= | Silent (SNP) | VAF 85/581 reads (15%) | catalogued as COSV56330387; called by muse, mutect2, varscan2
- NAV3 | c.207C>A p.P69= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as COSV57098610; called by muse, mutect2, varscan2
- NCAM2 | c.409C>A p.R137= | Silent (SNP) | VAF 13/245 reads (5%) | catalogued as COSV53054950, COSV99524564; called by muse, mutect2
- NF1 | c.6603C>T p.S2201= (on ENST00000358273 / NM_001042492.3; = p.S2180= on NM_000267.3) | Silent (SNP) | VAF 69/334 reads (21%) | called by muse, mutect2, varscan2
- NFKBID | c.771G>T p.G257= (on ENST00000396901; = p.G409= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 33/165 reads (20%) | called by muse, mutect2, varscan2
- NKX6-3 | c.195G>A p.A65= | Silent (SNP) | VAF 14/137 reads (10%) | catalogued as rs930445700; called by muse, mutect2, varscan2
- NLGN2 | c.1881G>A p.T627= | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as rs747379386, COSV57212716; called by muse, mutect2, varscan2
- NOMO3 | c.318G>A p.E106= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- NOS1AP | c.720A>T p.L240= | Silent (SNP) | VAF 70/754 reads (9%) | called by muse, mutect2
- NRP1 | c.1716C>T p.G572= | Silent (SNP) | VAF 23/323 reads (7%) | catalogued as rs543705855, COSV55171669, COSV99589814; called by muse, mutect2
- OCA2 | c.2047C>T p.L683= | Silent (SNP) | VAF 86/376 reads (23%) | called by muse, mutect2, varscan2
- OR10J3 | c.114G>T p.L38= | Silent (SNP) | VAF 26/450 reads (6%) | called by muse, mutect2
- OR11G2 | c.648A>T p.L216= | Silent (SNP) | VAF 54/440 reads (12%) | called by muse, mutect2, varscan2
- OR1L1 | c.249C>T p.P83= (on ENST00000373686; = p.P33= on NM_001005236.3) | Silent (SNP) | VAF 32/295 reads (11%) | catalogued as rs377748271; called by muse, mutect2, varscan2
- OR4Q3 | c.384C>A p.A128= | Silent (SNP) | VAF 23/418 reads (6%) | catalogued as COSV59179816; called by muse, mutect2
- OR5D18 | c.174C>G p.T58= | Silent (SNP) | VAF 38/171 reads (22%) | called by muse, mutect2, varscan2
- OR5H15 | c.108C>G p.L36= | Silent (SNP) | VAF 17/435 reads (4%) | catalogued as COSV62947765; called by muse, mutect2
- OR5T2 | c.970C>T p.L324= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV57590199; called by muse, varscan2
- OR6X1 | c.141G>A p.V47= | Silent (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- OTUD7A | c.738G>C p.L246= | Silent (SNP) | VAF 59/255 reads (23%) | called by muse, mutect2, varscan2
- OVCH1 | c.1749C>A p.P583= | Silent (SNP) | VAF 51/408 reads (13%) | catalogued as rs929481308, COSV58966114; called by muse, mutect2, varscan2
- PAPPA2 | c.4143G>A p.Q1381= | Silent (SNP) | VAF 96/373 reads (26%) | catalogued as COSV100868055, COSV62790335; called by muse, mutect2, varscan2
- PARP14 | c.1797G>A p.K599= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as COSV71735151; called by muse, mutect2, varscan2
- PAX2 | c.747G>A p.K249= (on ENST00000428433 / NM_003987.5; = p.K226= on NM_000278.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/566 reads (11%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2136G>T p.V712= | Silent (SNP) | VAF 101/421 reads (24%) | catalogued as COSV100974577; called by muse, mutect2, varscan2
- PCDHGA6 | c.2088G>T p.A696= | Silent (SNP) | VAF 79/420 reads (19%) | catalogued as rs758847977, COSV99544076; called by muse, mutect2, varscan2
- PHF19 | c.1035C>T p.P345= | Silent (SNP) | VAF 61/346 reads (18%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1326C>A p.A442= | Silent (SNP) | VAF 37/258 reads (14%) | called by muse, mutect2, varscan2
- PKHD1 | c.6949T>C p.L2317= | Silent (SNP) | VAF 99/553 reads (18%) | catalogued as COSV61858401; called by muse, mutect2, varscan2
- PKP4 | c.2163G>T p.L721= | Silent (SNP) | VAF 27/290 reads (9%) | called by muse, mutect2
- PLPPR5 | c.411A>G p.V137= | Silent (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- PLVAP | c.318C>A p.R106= | Silent (SNP) | VAF 53/264 reads (20%) | catalogued as COSV53084087; called by muse, mutect2, varscan2
- POTEJ | c.2946C>A p.A982= | Silent (SNP) | VAF 58/1096 reads (5%) | called by muse, mutect2
- PPIAL4D | c.393G>A p.K131= | Silent (SNP) | VAF 50/1388 reads (4%) | called by muse, mutect2
- PRKAG3 | c.1149G>A p.L383= | Silent (SNP) | VAF 49/440 reads (11%) | catalogued as COSV52104036; called by muse, mutect2, varscan2
- PTCHD4 | c.217C>T p.L73= | Silent (SNP) | VAF 37/298 reads (12%) | called by muse, mutect2
- RAD51B | c.465A>T p.I155= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV66843037; called by muse, mutect2, varscan2
- REV3L | c.7344T>C p.Y2448= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- RP1L1 | c.6648G>A p.E2216= | Silent (SNP) | VAF 72/608 reads (12%) | catalogued as rs765685639; called by muse, mutect2, varscan2
- SALL2 | c.2346C>T p.S782= | Silent (SNP) | VAF 22/474 reads (5%) | called by muse, mutect2
- SALL3 | c.366C>A p.G122= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- SIDT2 | c.420C>G p.V140= | Silent (SNP) | VAF 13/379 reads (3%) | catalogued as rs1203326775; called by muse, mutect2
- SLC11A2 | c.1701G>T p.L567= (on ENST00000394904 / NM_001379455.1; = p.L538= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/430 reads (17%) | catalogued as COSV100014772; called by muse, mutect2, varscan2
- SMCHD1 | c.2589A>G p.P863= | Silent (SNP) | VAF 18/152 reads (12%) | called by mutect2, varscan2
- SMO | c.525T>A p.P175= | Silent (SNP) | VAF 50/145 reads (34%) | called by muse, varscan2
- SNRNP200 | c.3051C>T p.V1017= | Silent (SNP) | VAF 30/782 reads (4%) | catalogued as rs1346939824; called by muse, mutect2
- SPNS1 | c.174G>T p.S58= | Silent (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- SPTA1 | c.3954C>G p.A1318= | Silent (SNP) | VAF 51/689 reads (7%) | catalogued as COSV100933983; called by muse, mutect2
- SRGAP1 | c.1878G>T p.S626= | Silent (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- SYT13 | c.903C>A p.A301= | Silent (SNP) | VAF 50/338 reads (15%) | called by muse, mutect2, varscan2
- SZT2 | c.1152C>T p.A384= | Silent (SNP) | VAF 18/246 reads (7%) | called by muse, mutect2
- TBR1 | c.123G>T p.S41= | Silent (SNP) | VAF 26/256 reads (10%) | catalogued as COSV67418055; called by muse, mutect2
- TCAIM | c.372G>T p.V124= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs150831975, COSV61241727; called by muse, mutect2, varscan2
- TGM5 | c.1140C>A p.A380= (on ENST00000220420 / NM_201631.4; = p.A298= on NM_004245.4) | Silent (SNP) | VAF 163/641 reads (25%) | called by mutect2, varscan2
- TIMD4 | c.1038G>A p.S346= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as rs145512953; called by muse, mutect2, varscan2
- TNKS | c.78G>A p.A26= | Silent (SNP) | VAF 17/216 reads (8%) | called by muse, mutect2
- UBA52 | c.183C>T p.I61= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs1191250721; called by muse, mutect2, varscan2
- VCAN | c.765C>A p.L255= | Silent (SNP) | VAF 52/324 reads (16%) | called by muse, mutect2, varscan2
- WDFY4 | c.3282G>T p.T1094= | Silent (SNP) | VAF 82/503 reads (16%) | called by muse, mutect2, varscan2
- WT1 | c.348G>A p.P116= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- ZBTB10 | c.1086T>C p.I362= | Silent (SNP) | VAF 31/311 reads (10%) | called by muse, mutect2
- ZBTB34 | c.708G>T p.V236= | Silent (SNP) | VAF 56/367 reads (15%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3522T>A p.T1174= | Silent (SNP) | VAF 21/460 reads (5%) | called by muse, mutect2
- ZCWPW2 | c.93T>G p.V31= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as rs1279436174; called by muse, mutect2, varscan2
- ZNF354B | c.795A>T p.T265= | Silent (SNP) | VAF 68/247 reads (28%) | called by muse, mutect2, varscan2
- ZNF37A | c.1557G>C p.G519= | Silent (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- ZNF432 | c.894C>T p.F298= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ZNF705A | c.363G>T p.S121= | Silent (SNP) | VAF 44/308 reads (14%) | catalogued as rs753028243, COSV100828359; called by muse, mutect2, varscan2
- ZNF728 | c.849C>G p.P283= | Silent (SNP) | VAF 66/389 reads (17%) | called by muse, mutect2, varscan2
- ZNF768 | c.1272C>T p.A424= | Silent (SNP) | VAF 9/202 reads (4%) | called by muse, mutect2
- ZSCAN5A | c.918C>T p.S306= | Silent (SNP) | VAF 56/493 reads (11%) | called by muse, mutect2, varscan2
- AC026410.1 | n.731A>G | RNA (SNP) | VAF 75/488 reads (15%) | called by muse, mutect2, varscan2
- AC138647.1 | chr8:141518716 A>G | 3'Flank (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- ACSL6 | chr5:131947607 T>A | 3'Flank (SNP) | VAF 54/280 reads (19%) | called by muse, mutect2, varscan2
- ADARB2 | c.1683-48C>A | Intron (SNP) | VAF 48/216 reads (22%) | called by muse, mutect2, varscan2
- AFDN | chr6:167826138 C>T | 5'Flank (SNP) | VAF 19/490 reads (4%) | called by muse, mutect2
- AL033381.1 | n.622T>A | RNA (SNP) | VAF 22/173 reads (13%) | called by muse, mutect2, varscan2
- AL161729.4 | chr9:95516736 C>G | 3'Flank (SNP) | VAF 52/291 reads (18%) | catalogued as COSV64609717; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847942 G>C | 5'Flank (SNP) | VAF 15/192 reads (8%) | called by muse, mutect2
- APBA2 | c.1524+53G>C | Intron (SNP) | VAF 41/204 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.1200+109G>T | Intron (SNP) | VAF 32/320 reads (10%) | catalogued as COSV99771347; called by muse, mutect2
- ARL13B | c.130+639G>C | Intron (SNP) | VAF 10/88 reads (11%) | called by muse, mutect2
- ATP1A3 | c.*346G>T | 3'UTR (SNP) | VAF 71/282 reads (25%) | called by muse, mutect2, varscan2
- BMP7 | c.1036-50T>C | Intron (SNP) | VAF 105/425 reads (25%) | called by muse, mutect2, varscan2
- CALCR | c.-39G>C | 5'UTR (SNP) | VAF 34/179 reads (19%) | called by muse, mutect2, varscan2
- CAMK2B | c.415-1427C>T | Intron (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- COL3A1 | c.3526-46C>A | Intron (SNP) | VAF 58/270 reads (21%) | called by muse, mutect2, varscan2
- COL6A1 | c.1741-23C>T | Intron (SNP) | VAF 61/422 reads (14%) | called by muse, mutect2, varscan2
- CSMD2 | c.8312-7405C>A | Intron (SNP) | VAF 12/152 reads (8%) | catalogued as COSV53943285; called by muse, mutect2
- DCHS2 | n.6368G>T | RNA (SNP) | VAF 22/358 reads (6%) | catalogued as COSV61774766, COSV61776827; called by muse, mutect2
- DCLK2 | c.961+931G>C | Intron (SNP) | VAF 42/270 reads (16%) | catalogued as rs755837325, COSV99651397; called by muse, mutect2, varscan2
- DLGAP3 | chr1:34905416 G>T | 5'Flank (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- DOCK2 | c.2800-48413G>A | Intron (SNP) | VAF 52/297 reads (18%) | called by muse, mutect2, varscan2
- EDARADD | c.61+1118C>A | Intron (SNP) | VAF 18/556 reads (3%) | called by muse, mutect2
- FAM90A27P | n.362C>T | RNA (SNP) | VAF 15/295 reads (5%) | catalogued as rs1024538345; called by muse, mutect2
- FAM90A27P | n.774G>T | RNA (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2, varscan2
- FBRS | chr16:30659694 C>T | 5'Flank (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- FOLH1B | n.960G>T | RNA (SNP) | VAF 27/192 reads (14%) | called by muse, mutect2, varscan2
- GLYATL3 | c.-8dup | 5'UTR (INS) | VAF 16/120 reads (13%) | called by mutect2, pindel, varscan2
- GPM6A | c.37+24850T>A | Intron (SNP) | VAF 73/270 reads (27%) | called by muse, varscan2
- GRB10 | c.1195-43G>A | Intron (SNP) | VAF 74/466 reads (16%) | catalogued as rs372429316; called by muse, mutect2, varscan2
- GRIPAP1 | c.458-94G>A | Intron (SNP) | VAF 19/57 reads (33%) | called by muse, varscan2
- IGF2BP2 | c.240-18269C>A | Intron (SNP) | VAF 80/374 reads (21%) | called by muse, mutect2, varscan2
- ITK | c.496-46C>A | Intron (SNP) | VAF 112/396 reads (28%) | called by muse, varscan2
- ITK | c.496-16T>G | Intron (SNP) | VAF 86/562 reads (15%) | called by muse, varscan2
- LDHA | chr11:18394579 C>A | 5'Flank (SNP) | VAF 54/401 reads (13%) | called by muse, mutect2, varscan2
- LRRC37A6P | n.2181C>G | RNA (SNP) | VAF 26/532 reads (5%) | called by muse, mutect2
- METTL17 | c.76-18A>G | Intron (SNP) | VAF 27/350 reads (8%) | called by muse, mutect2
- MIR1283-1 | n.39G>T | RNA (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2, varscan2
- MMGT1 | c.-336G>T | 5'UTR (SNP) | VAF 26/131 reads (20%) | called by muse, varscan2
- MYADML | n.1100C>A | RNA (SNP) | VAF 65/346 reads (19%) | called by muse, mutect2, varscan2
- NAPSB | n.779G>A | RNA (SNP) | VAF 31/309 reads (10%) | called by muse, mutect2, varscan2
- NET1 | c.-19C>T | 5'UTR (SNP) | VAF 28/160 reads (18%) | catalogued as rs1316472990; called by muse, mutect2, varscan2
- NLRP2 | c.2709-42T>G | Intron (SNP) | VAF 46/415 reads (11%) | catalogued as rs1445038463; called by muse, mutect2, varscan2
- NT5DC1 | c.921+414G>C | Intron (SNP) | VAF 27/187 reads (14%) | called by muse, mutect2, varscan2
- OR2L1P | n.726G>T | RNA (SNP) | VAF 103/440 reads (23%) | catalogued as rs1220323800; called by muse, mutect2, varscan2
- PASK | c.3334-37C>A | Intron (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2
- PLA2G6 | c.1349-16G>T | Intron (SNP) | VAF 55/434 reads (13%) | called by muse, mutect2, varscan2
- POLR3B | c.2985-1207G>C | Intron (SNP) | VAF 14/243 reads (6%) | called by muse, mutect2
- SMARCA2 | c.3982-1824T>G | Intron (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.232+23G>C | Intron (SNP) | VAF 19/128 reads (15%) | called by muse, mutect2, varscan2
- SYNE1 | c.1351-194T>C | Intron (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- TBRG4 | c.736-231C>T | Intron (SNP) | VAF 44/187 reads (24%) | called by muse, mutect2, varscan2
- TMEM135 | c.510-18493G>T | Intron (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- TNNT3 | chr11:1938597 T>C | 3'Flank (SNP) | VAF 48/277 reads (17%) | called by muse, mutect2, varscan2
- TTN | c.10360+3331C>T | Intron (SNP) | VAF 28/440 reads (6%) | catalogued as rs1377229995; called by muse, mutect2
- URM1 | chr9:128371369 G>T | 5'Flank (SNP) | VAF 18/160 reads (11%) | called by muse, mutect2, varscan2
- USP17L30 | chr4:9369051 C>G | 3'Flank (SNP) | VAF 45/543 reads (8%) | called by muse, mutect2, varscan2
- VWA5B1 | c.710-83C>A | Intron (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- XPO6 | c.3276+21G>T | Intron (SNP) | VAF 58/388 reads (15%) | called by muse, mutect2, varscan2
- YJU2 | chr19:4247071 G>A | 5'Flank (SNP) | VAF 64/289 reads (22%) | called by muse, mutect2, varscan2
- ZNF252P | n.329G>A | RNA (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- ZNF292 | c.538+4072G>T | Intron (SNP) | VAF 22/170 reads (13%) | catalogued as rs918128613; called by muse, mutect2, varscan2
- ZNF354B | c.-14G>A | 5'UTR (SNP) | VAF 33/638 reads (5%) | called by muse, mutect2
